Somatic mutation profile of tumor specimen TCGA-A4-A6HP-01A (aliquot TCGA-A4-A6HP-01A-11D-A31X-10) from TCGA case TCGA-A4-A6HP, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.9 years (24,447 days).
Specimen TCGA-A4-A6HP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f86ebb20-5a17-4368-883f-f5121d37e59d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-A6HP-10A (Blood Derived Normal), aliquot TCGA-A4-A6HP-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf2fe8a9-181e-4a0e-97b9-c22db54e06e8

The open-access MAF lists 87 somatic variants for this specimen: 69 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 57, Silent 18, Frame Shift Del 5, Frame Shift Ins 3, Splice Site 2, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC131160.1 | c.31T>C p.W11R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.059); catalogued as rs763167412, COSV57702328; called by muse, mutect2, varscan2
- ADCY6 | c.2219C>T p.A740V | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV57170542; called by muse, mutect2, varscan2
- ADGRD1 | c.499T>G p.W167G | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55457372; called by muse, mutect2, varscan2
- AGRN | c.5541C>A p.F1847L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV65072310; called by muse, mutect2, varscan2
- AHCY | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV54154516; called by muse, varscan2
- ALPK1 | c.269A>T p.Q90L | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV51591968; called by muse, mutect2, varscan2
- ANXA4 | c.497A>T p.N166I | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.156); catalogued as COSV67849551; called by muse, mutect2, varscan2
- ATP11A | c.675-1G>A p.X225_splice | Splice Site (SNP) | VAF 16/53 reads (30%) | catalogued as COSV52124471; called by muse, mutect2, varscan2
- CDHR2 | c.3653G>A p.R1218Q | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.273); catalogued as rs764089283, COSV56145191; called by muse, mutect2, varscan2
- COG6 | c.502A>G p.S168G | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV62995103, COSV62998009; called by muse, mutect2, varscan2
- CPEB4 | c.418T>G p.L140V | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54176148; called by muse, mutect2
- CR1L | c.1391G>T p.S464I | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV54331485; called by muse, mutect2
- CR1L | c.1392C>G p.S464R | Missense Mutation (SNP) | VAF 70/263 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV54331491; called by muse, mutect2
- CTRB1 | c.160A>G p.K54E | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100727232; called by muse, mutect2, varscan2
- DSP | c.6094G>A p.V2032I | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.351); catalogued as rs749307935, COSV65796008; called by muse, mutect2, varscan2
- ECT2L | c.92T>C p.I31T | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV62887197; called by muse, mutect2, varscan2
- FER1L6 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 84/255 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1173623676, COSV67550806, COSV67552811; called by muse, mutect2, varscan2
- GALNT10 | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 57/148 reads (39%) | catalogued as rs1176591241, COSV51734312; called by muse, mutect2, varscan2
- HCAR1 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs915639443, COSV63670902; called by muse, mutect2, varscan2
- HOXB9 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as COSV60817789; called by muse, mutect2
- HOXC4 | c.82T>A p.Y28N | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57700628; called by muse, mutect2, varscan2
- ILVBL | c.1859T>C p.I620T | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs754987632, COSV54622490; called by muse, mutect2, varscan2
- IMMT | c.2111A>T p.E704V | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747799315, COSV54483480; called by muse, mutect2, varscan2
- INPP5B | c.1789T>C p.C597R (on ENST00000373023; = p.C517R on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV65963071; called by muse, mutect2, varscan2
- KLHL18 | c.666G>T p.E222D | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV51748665; called by muse, varscan2
- KLHL18 | c.667C>A p.L223M | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV51748677; called by muse, varscan2
- KLHL21 | c.1355A>G p.D452G | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV66554256; called by muse, mutect2, varscan2
- MPHOSPH10 | c.650T>G p.I217R | Missense Mutation (SNP) | VAF 152/369 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as rs1467717309, COSV54907202; called by muse, mutect2, varscan2
- MSL1 | c.824A>G p.N275S (on ENST00000398532 / NM_001365919.1; = p.N12S on NM_001012241.2) | Missense Mutation (SNP) | VAF 100/212 reads (47%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.021); catalogued as COSV59899828; called by muse, mutect2, varscan2
- MTMR3 | c.755A>C p.H252P | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV60308759; called by muse, mutect2, varscan2
- MUC4 | c.480A>T p.E160D | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.224); catalogued as COSV62194363; called by muse, mutect2, varscan2
- NDUFB10 | c.266A>T p.D89V | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51911024; called by muse, mutect2, varscan2
- NDUFB4 | c.224A>G p.N75S | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as rs760344622, COSV51742923; called by muse, mutect2, varscan2
- NEK10 | c.2505+2T>A p.X835_splice | Splice Site (SNP) | VAF 37/117 reads (32%) | catalogued as COSV55365513; called by muse, mutect2, varscan2
- NIF3L1 | c.1048C>A p.L350I (on ENST00000409020 / NM_001369444.1; = p.L323I on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1440554235, COSV62901104; called by muse, mutect2, varscan2
- NMD3 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs1211790179, COSV63619655; called by muse, mutect2, varscan2
- NOTCH1 | c.2282C>A p.P761H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53094145; called by muse, mutect2, varscan2
- NPAT | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV53721791; called by muse, mutect2, varscan2
- OBSCN | c.15768G>C p.E5256D | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV52828898; called by muse, mutect2, varscan2
- PIAS2 | c.1145C>T p.T382I | Missense Mutation (SNP) | VAF 39/306 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376294323, COSV61345429; called by muse, mutect2, varscan2
- POMK | c.986A>G p.E329G | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV58858620; called by muse, mutect2, varscan2
- PPARGC1B | c.1426G>A p.V476M | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780417101, COSV58527170, COSV58528707; called by muse, mutect2, varscan2
- PPRC1 | c.3974G>A p.R1325H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as rs764176836, COSV53388542; called by muse, mutect2, varscan2
- RNF10 | c.312C>A p.S104R | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.094); catalogued as COSV58048210; called by muse, mutect2, varscan2
- SAXO2 | c.992C>A p.T331K | Missense Mutation (SNP) | VAF 127/384 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV59755395; called by muse, mutect2, varscan2
- SLC13A3 | c.947T>C p.I316T | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.328); catalogued as COSV51723058; called by muse, mutect2, varscan2
- SLC22A10 | c.1342A>G p.T448A | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60423495; called by muse, mutect2, varscan2
- SMPD4 | c.1495C>T p.P499S (on ENST00000409031 / NM_017951.4; = p.P470S on NM_017751.4) | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.878); catalogued as COSV60082892; called by muse, mutect2, varscan2
- SOX5 | c.1108T>C p.S370P | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.809); catalogued as COSV58648404; called by muse, mutect2, varscan2
- SURF2 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.846); catalogued as COSV64332711; called by muse, mutect2
- TMEM170B | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65158141; called by muse, mutect2, varscan2
- TMEM192 | c.691C>A p.L231I | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV60586315; called by muse, mutect2, varscan2
- TMEM86B | c.31A>G p.K11E | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV58985316; called by muse, mutect2, varscan2
- TRAP1 | c.1710C>T p.A570= | Splice Region (SNP) | VAF 10/25 reads (40%) | catalogued as rs749434626, COSV55913937; called by muse, mutect2, varscan2
- XIRP2 | c.4850T>A p.L1617Q (on ENST00000628543; = p.L1792Q on NM_152381.6) | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54734054; called by muse, varscan2
- ZBTB5 | c.1000C>A p.L334M | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57041838; called by muse, mutect2, varscan2
- ZNF146 | c.270C>A p.H90Q | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100757795, COSV61932671; called by muse, mutect2, varscan2
- ZNF275 | c.1213T>A p.C405S | Missense Mutation (SNP) | VAF 52/71 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV64705428; called by muse, mutect2, varscan2
- ZNF536 | c.3600C>G p.D1200E | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs545401755, COSV62834023; called by muse, mutect2, varscan2
- ZNF586 | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.479); catalogued as COSV101656740; called by muse, varscan2
- ZNF721 | c.1501T>C p.S501P (on ENST00000338977; = p.S513P on NM_133474.4) | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.804); catalogued as COSV59097128; called by muse, mutect2, varscan2
- ACOT11 | c.439_446del p.A147Rfs*30 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- AQP3 | c.338dup p.A116Cfs*10 | Frame Shift Ins (INS) | VAF 41/141 reads (29%) | called by mutect2, pindel, varscan2
- RIMS1 | c.3944_3945del p.D1315Afs*8 | Frame Shift Del (DEL) | VAF 29/117 reads (25%) | called by mutect2, pindel, varscan2
- RINT1 | c.879del p.K293Nfs*18 | Frame Shift Del (DEL) | VAF 57/198 reads (29%) | called by mutect2, pindel, varscan2
- RNPEP | c.659_669del p.F220Sfs*19 | Frame Shift Del (DEL) | VAF 35/152 reads (23%) | called by mutect2, pindel, varscan2
- UGT1A9 | c.248dup p.E84Gfs*32 | Frame Shift Ins (INS) | VAF 63/219 reads (29%) | called by mutect2, pindel, varscan2
- ZC3H4 | c.3900del p.C1302Afs*25 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | called by mutect2, pindel, varscan2
- ZZEF1 | c.3084dup p.V1029Sfs*42 | Frame Shift Ins (INS) | VAF 100/232 reads (43%) | called by mutect2, pindel, varscan2
- ALPK3 | c.4512G>A p.L1504= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV51931619, COSV51939788; called by muse, mutect2, varscan2
- CARD10 | c.1761G>C p.R587= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV52660103; called by muse, mutect2, varscan2
- CITED2 | c.213T>C p.H71= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV62726209; called by muse, mutect2, varscan2
- COQ4 | c.609G>A p.P203= | Silent (SNP) | VAF 65/174 reads (37%) | catalogued as rs770218973, COSV55958022; called by muse, mutect2, varscan2
- DNAJC10 | c.678G>T p.V226= | Silent (SNP) | VAF 104/320 reads (33%) | catalogued as COSV51146773; called by muse, mutect2, varscan2
- ELAC2 | c.1920T>C p.C640= | Silent (SNP) | VAF 58/117 reads (50%) | catalogued as rs753389017, COSV52402782; called by muse, mutect2, varscan2
- GYS1 | c.981T>C p.F327= | Silent (SNP) | VAF 57/158 reads (36%) | catalogued as rs777163673, COSV54405377; called by muse, mutect2, varscan2
- HSPE1-MOB4 | c.87A>G p.G29= | Silent (SNP) | VAF 132/347 reads (38%) | catalogued as COSV52100220; called by muse, mutect2, varscan2
- IPO5 | c.2337A>T p.V779= | Silent (SNP) | VAF 57/153 reads (37%) | catalogued as COSV55159868; called by muse, mutect2, varscan2
- KDM6B | c.54C>A p.A18= | Silent (SNP) | VAF 38/170 reads (22%) | catalogued as COSV54682417; called by muse, mutect2, varscan2
- LCOR | c.1722T>G p.S574= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as COSV53718343; called by muse, mutect2, varscan2
- LTBP2 | c.4659C>T p.C1553= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV56214122; called by muse, mutect2
- PDCD4 | c.1323A>G p.K441= | Silent (SNP) | VAF 62/196 reads (32%) | catalogued as COSV54525616; called by muse, mutect2, varscan2
- SLC22A10 | c.747A>T p.G249= | Silent (SNP) | VAF 59/147 reads (40%) | catalogued as COSV60423487; called by muse, mutect2, varscan2
- TBC1D28 | c.264T>C p.Y88= | Silent (SNP) | VAF 54/127 reads (43%) | catalogued as rs1567876837, COSV61508130; called by muse, mutect2, varscan2
- TMF1 | c.3150A>G p.Q1050= | Silent (SNP) | VAF 57/185 reads (31%) | catalogued as rs1273357363, COSV68375925; called by muse, mutect2, varscan2
- UVSSA | c.1446G>A p.A482= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as rs114098503, COSV66230945; called by muse, mutect2, varscan2
- ZSCAN29 | c.2112A>G p.K704= | Silent (SNP) | VAF 42/154 reads (27%) | catalogued as COSV67823357; called by muse, mutect2
